Somatic mutation profile of tumor specimen C3L-00368-01 (aliquot CPT0063730006) from CPTAC case C3L-00368, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 67.4 years (24,636 days).
Specimen C3L-00368-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28925821-36ac-4f13-a2fa-8d45934be7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00368-31 (Blood Derived Normal), aliquot CPT0065310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/063f8a30-5e4a-497a-8bad-c3550d4a474f

The open-access MAF lists 143 somatic variants for this specimen: 98 protein-altering or splice-affecting, 26 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 26, Intron 9, Nonsense Mutation 7, Frame Shift Del 5, 3'UTR 5, Frame Shift Ins 4, RNA 4, Splice Region 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 61/323 reads (19%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2156G>C p.G719A | Missense Mutation (SNP) | VAF 68/368 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913428, COSV51769339, COSV51771914, COSV51779524; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 44/237 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.1672C>A p.Q558K | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56645361; called by muse, mutect2, varscan2
- ARX | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.146); catalogued as rs1291778310; called by muse, mutect2
- B4GALT2 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759995142; called by muse, mutect2, varscan2
- CCDC87 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as COSV59578333, COSV59580196; called by muse, mutect2, varscan2
- EHD3 | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100434810; called by muse, mutect2, varscan2
- FABP6 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67437803; called by muse, mutect2
- FOXO4 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100447089; called by muse, mutect2
- GUF1 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763786190, COSV55781654; called by muse, mutect2, varscan2
- HS2ST1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV63354117; called by muse, mutect2
- ITGAD | c.201C>A p.C67* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as rs560106374, COSV66760739; called by muse, mutect2, varscan2
- KRT76 | c.1396C>A p.R466S | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs147945662; called by muse, mutect2, varscan2
- MTRR | c.1249G>T p.D417Y (on ENST00000264668; = p.D390Y on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 167/486 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52946401; called by muse, mutect2, varscan2
- NOD2 | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 169/846 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs104895484, CM065050; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- PCDH1 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472862636, COSV99745298; called by muse, mutect2
- PLA2R1 | c.3637G>T p.D1213Y | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51776417; called by muse, mutect2, varscan2
- PORCN | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs782565137; called by muse, mutect2, varscan2
- RAB33A | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV57061485, COSV57063419; called by muse, mutect2
- SNTG1 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV52462211; called by muse, mutect2, varscan2
- ST18 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as rs779376419; called by muse, mutect2, varscan2
- TBX15 | c.1490G>T p.G497V (on ENST00000369429 / NM_001330677.2; = p.G391V on NM_152380.3) | Missense Mutation (SNP) | VAF 120/652 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as COSV52871059; called by muse, mutect2, varscan2
- TMTC1 | c.1556C>A p.A519E (on ENST00000539277 / NM_001193451.2; = p.A411E on NM_175861.3) | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55479735; called by muse, mutect2, varscan2
- TRPM2 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765214450; called by muse, varscan2
- UGT8 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60419242; called by muse, mutect2, varscan2
- ZNF679 | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs559743213, COSV55376309; called by muse, mutect2, varscan2
- ADCY5 | c.1404G>T p.V468= | Splice Region (SNP) | VAF 22/144 reads (15%) | called by muse, varscan2
- ADCY8 | c.866T>A p.L289H | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALOXE3 | c.2063_2074del p.E688_Q691del | In Frame Del (DEL) | VAF 44/257 reads (17%) | called by mutect2, pindel
- ANO2 | c.2774C>A p.P925Q (on ENST00000356134 / NM_001278597.3; = p.P929Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BEGAIN | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRF1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- BRINP1 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- BTN3A3 | c.1579G>T p.V527L | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 67/404 reads (17%) | called by muse, mutect2, varscan2
- CAPN15 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARTPT | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CASS4 | c.1579T>G p.Y527D | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDH9 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDHR1 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHD2 | c.3854_3860del p.K1285Tfs*6 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- COLQ | c.968A>G p.N323S | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CPNE4 | c.749del p.K250Rfs*3 | Frame Shift Del (DEL) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
- DDB1 | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAJC13 | c.3793_3796del p.L1265Gfs*14 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel*, varscan2
- DOP1B | c.2942G>C p.G981A | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.783); called by muse, mutect2
- DOT1L | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 66/354 reads (19%) | called by muse, mutect2, varscan2
- EDARADD | c.357G>T p.Q119H (on ENST00000334232 / NM_145861.4; = p.Q109H on NM_080738.4) | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- EYA4 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.4972C>A p.R1658S | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GIGYF2 | c.2828dup p.L944Afs*5 | Frame Shift Ins (INS) | VAF 60/316 reads (19%) | called by pindel, varscan2
- GLYATL1 | c.744G>C p.M248I (on ENST00000317391 / NM_001354699.1; = p.M279I on NM_080661.4) | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.258); called by muse, mutect2
- GPR78 | c.523A>C p.T175P | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GRHL2 | c.1559A>T p.E520V | Missense Mutation (SNP) | VAF 68/468 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHV3-73 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KIAA1755 | c.2362A>C p.T788P | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KRBA1 | c.2497dup p.T833Nfs*52 | Frame Shift Ins (INS) | VAF 62/304 reads (20%) | called by mutect2, pindel, varscan2
- MGAM2 | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MSH3 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MST1R | c.2863C>T p.Q955* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.8605C>A p.P2869T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- NBAS | c.4611G>T p.L1537F | Missense Mutation (SNP) | VAF 84/414 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NEFH | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NOS1 | c.4301C>G p.S1434C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NOTCH4 | c.995G>T p.C332F | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOVA1 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4E2 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR5A1 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5T2 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR8B2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); called by muse, varscan2
- PCDHB8 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 138/1995 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PHF3 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2, varscan2
- PPP1R10 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRAMEF15 | c.1231T>C p.C411R | Missense Mutation (SNP) | VAF 30/952 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- PSG11 | c.994A>T p.N332Y | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PTDSS2 | c.1373_1374del p.V458Gfs*38 | Frame Shift Del (DEL) | VAF 50/351 reads (14%) | called by mutect2, pindel, varscan2
- RRBP1 | c.782dup p.A262Gfs*9 | Frame Shift Ins (INS) | VAF 57/336 reads (17%) | called by mutect2, pindel, varscan2
- RYR3 | c.1764G>T p.L588F | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELP | c.1280T>C p.I427T | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINE2 | c.920C>A p.P307Q | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- SERPINE2 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, varscan2
- SLC39A12 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- SRD5A1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.3317C>A p.T1106K | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TKFC | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TLR7 | c.2375T>A p.V792E | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.231); called by muse, mutect2
- TPH2 | c.1299G>T p.R433S | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TTC34 | c.1721A>T p.Y574F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TUT7 | c.2142T>G p.N714K | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- U2SURP | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- UBQLN1 | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.214); called by muse, mutect2
- UBR4 | c.15024_15046del p.R5009Lfs*15 | Frame Shift Del (DEL) | VAF 54/232 reads (23%) | called by mutect2, pindel
- UBR4 | c.1490A>C p.H497P | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- XPO5 | c.3381_3382insA p.Q1128Tfs*3 | Frame Shift Ins (INS) | VAF 31/233 reads (13%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.3411G>C p.E1137D | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF566 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZZEF1 | c.7378G>T p.D2460Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADA | c.153C>A p.G51= | Silent (SNP) | VAF 74/419 reads (18%) | catalogued as COSV100866638, COSV65739807; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.87G>T p.S29= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1530A>T p.P510= (on ENST00000409202 / NM_001007231.3; = p.P502= on NM_014882.3) | Silent (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- CDHR1 | c.1989C>A p.S663= | Silent (SNP) | VAF 46/263 reads (17%) | called by muse, mutect2, varscan2
- DDX56 | c.810G>T p.R270= | Silent (SNP) | VAF 46/412 reads (11%) | called by muse, mutect2
- DRD2 | c.1062C>A p.S354= | Silent (SNP) | VAF 91/413 reads (22%) | called by muse, mutect2, varscan2
- DSG3 | c.771G>A p.V257= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- FAT4 | c.447C>T p.S149= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- FPGS | c.1512C>T p.P504= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as rs374531817; called by muse, mutect2, varscan2
- FSCN3 | c.162G>T p.V54= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- GDA | c.1029C>A p.I343= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99429613; called by muse, mutect2, varscan2
- GJD2 | c.402C>A p.G134= | Silent (SNP) | VAF 31/222 reads (14%) | catalogued as rs771398681; called by muse, mutect2, varscan2
- KCNH7 | c.3204C>A p.P1068= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- LCN1 | c.102G>A p.T34= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs374415872; called by muse, mutect2, varscan2
- MEGF10 | c.1041C>A p.G347= | Silent (SNP) | VAF 142/556 reads (26%) | catalogued as rs138524411; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEGF8 | c.7785G>T p.R2595= (on ENST00000251268 / NM_001271938.2; = p.R2528= on NM_001410.3) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs374927201; called by muse, mutect2, varscan2
- MXRA5 | c.105C>A p.V35= | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- NAV2 | c.1371C>T p.P457= (on ENST00000396087 / NM_001244963.2; = p.P434= on NM_145117.5) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV62333778; called by muse, mutect2, varscan2
- OR13H1 | c.312C>T p.S104= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as COSV58547065; called by muse, mutect2, varscan2
- PDE3B | c.159C>T p.R53= | Silent (SNP) | VAF 47/177 reads (27%) | called by muse, mutect2, varscan2
- PPP3CC | c.57C>A p.P19= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV51501116; called by muse, varscan2
- QRSL1 | c.927G>T p.G309= | Silent (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- STAG1 | c.3093C>T p.T1031= | Silent (SNP) | VAF 32/266 reads (12%) | catalogued as rs150499884; called by muse, mutect2, varscan2
- SVEP1 | c.10282C>A p.R3428= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- UBR4 | c.1491C>T p.H497= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs1349914900; called by muse, mutect2, varscan2
- ZNF106 | c.4185A>G p.K1395= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs773489889; called by muse, mutect2, varscan2
- AAK1 | c.*9796G>A | 3'UTR (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- ATG16L2 | c.319-79C>A | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- BABAM2 | c.1088+11611G>C | Intron (SNP) | VAF 29/144 reads (20%) | catalogued as COSV59627027; called by muse, mutect2, varscan2
- CHRNA4 | c.*3418G>T | 3'UTR (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2652C>T | Intron (SNP) | VAF 11/330 reads (3%) | catalogued as COSV100153663; called by muse, mutect2
- FAM205BP | n.1269A>T | RNA (SNP) | VAF 37/337 reads (11%) | called by muse, mutect2, varscan2
- HTR3A | c.*241T>A | 3'UTR (SNP) | VAF 91/397 reads (23%) | called by muse, mutect2, varscan2
- KRT18P55 | n.796G>A | RNA (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- LINC02108 | n.332G>T | RNA (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- LINC02108 | n.331G>T | RNA (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- NELL1 | c.1549+54893G>T | Intron (SNP) | VAF 27/255 reads (11%) | called by muse, mutect2, varscan2
- ODF3 | c.413-17C>T | Intron (SNP) | VAF 44/263 reads (17%) | catalogued as rs775228950; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1003-38del | Intron (DEL) | VAF 43/165 reads (26%) | called by pindel, varscan2
- PCDHA10 | c.2388+4649C>A | Intron (SNP) | VAF 77/509 reads (15%) | called by muse, mutect2, varscan2
- PPP1R7 | c.819+636G>T | Intron (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- PRELID1 | c.*3A>C | 3'UTR (SNP) | VAF 34/238 reads (14%) | catalogued as COSV57463989; called by muse, mutect2, varscan2
- SPINT2 | c.392-41G>T | Intron (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568019 G>A | 5'Flank (SNP) | VAF 7/41 reads (17%) | catalogued as rs1175875199; called by mutect2, varscan2
- TMEM135 | c.*6434G>T | 3'UTR (SNP) | VAF 14/474 reads (3%) | called by muse, mutect2
